Somatic mutation profile of tumor specimen TCGA-K4-A5RJ-01A (aliquot TCGA-K4-A5RJ-01A-11D-A289-08) from TCGA case TCGA-K4-A5RJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.3 years (27,518 days).
Specimen TCGA-K4-A5RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 314e2171-29b7-4342-9c7a-7b667068d741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A5RJ-10A (Blood Derived Normal), aliquot TCGA-K4-A5RJ-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/762daebc-5c06-422c-a1ba-36d826578489

The open-access MAF lists 410 somatic variants for this specimen: 293 protein-altering or splice-affecting, 106 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 106, Nonsense Mutation 29, Intron 5, Splice Site 4, RNA 2, 5'Flank 2, 3'UTR 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 76/366 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0.291); catalogued as rs28933369, COSV54062237, COSV54066483, COSV54068502, COSV54077923, COSV54082404; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABCA12 | c.3868C>T p.L1290F (on ENST00000272895 / NM_173076.3; = p.L972F on NM_015657.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV55953546; called by muse, mutect2, varscan2
- ABCA13 | c.2900C>G p.S967* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV101330003, COSV70029659; called by muse, mutect2, varscan2
- ABCC4 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100972432; called by muse, mutect2, varscan2
- ACAP2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV58750678; called by muse, mutect2, varscan2
- ADAMTS18 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV51402058; called by muse, mutect2, varscan2
- ADGRB1 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100029494; called by muse, mutect2, varscan2
- AHSA1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53631360; called by muse, mutect2, varscan2
- ALMS1 | c.6289C>T p.H2097Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV52506383; called by muse, mutect2, varscan2
- ALPK3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV51931525; called by muse, mutect2
- AMY1A | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 85/451 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs769271241, COSV64410921; called by muse, mutect2, varscan2
- ANKRD50 | c.4110G>C p.Q1370H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as COSV72385327; called by muse, mutect2, varscan2
- ANXA9 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV64484411; called by muse, mutect2, varscan2
- AP3B2 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.166); catalogued as COSV55607978; called by muse, mutect2, varscan2
- ARL16 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1490722734, COSV61267127; called by muse, mutect2, varscan2
- ARSL | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66965015; called by muse, mutect2, varscan2
- ATG101 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61085037; called by muse, mutect2, varscan2
- ATG101 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV61085043; called by muse, mutect2, varscan2
- ATMIN | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55145605; called by muse, mutect2, varscan2
- ATP6AP2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs768989127, COSV65797125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1A | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56361517; called by muse, mutect2, varscan2
- AUP1 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV51206611; called by muse, mutect2, varscan2
- AWAT1 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.357); catalogued as COSV65738347; called by muse, mutect2, varscan2
- BCL2A1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51212992; called by muse, mutect2, varscan2
- BRF1 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV59267246; called by muse, mutect2, varscan2
- BUB1B | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.336); catalogued as COSV55010939; called by muse, mutect2, varscan2
- C20orf194 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 124/564 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768850665, COSV52695927; called by muse, mutect2, varscan2
- C9orf24 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV52620276; called by muse, mutect2, varscan2
- CACNA1A | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV64193614; called by muse, mutect2, varscan2
- CACNA1H | c.7031C>T p.A2344V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs770021151, COSV99326604; called by muse, mutect2
- CASP8AP2 | c.2244G>T p.M748I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99386956; called by muse, mutect2, varscan2
- CBLB | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV51423734; called by muse, mutect2, varscan2
- CCDC15 | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV61080867; called by muse, mutect2
- CCDC62 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV53431776; called by muse, mutect2, varscan2
- CCDC87 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV100039899; called by muse, mutect2, varscan2
- CCKBR | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV58099903; called by muse, mutect2, varscan2
- CCKBR | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV58099916; called by muse, mutect2, varscan2
- CDC42BPG | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV61346361; called by muse, mutect2, varscan2
- CDCA8 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV59238371, COSV59240888; called by muse, mutect2, varscan2
- CDH5 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100439172; called by muse, mutect2, varscan2
- CDK11A | c.1466G>C p.R489T (on ENST00000378633 / NM_001313896.2; = p.R486T on NM_024011.4) | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52307075; called by muse, mutect2, varscan2
- CEP97 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as COSV100511652; called by muse, mutect2, varscan2
- CFAP74 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54566052; called by muse, mutect2, varscan2
- CGB5 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100031987; called by muse, mutect2, varscan2
- CHD4 | c.1453C>G p.L485V (on ENST00000357008 / NM_001363606.2; = p.L498V on NM_001273.5) | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV58897171; called by muse, mutect2, varscan2
- CHI3L1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV55137542; called by muse, mutect2, varscan2
- CHIT1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV55145863; called by muse, mutect2, varscan2
- CLASP2 | c.654G>C p.M218I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56278850; called by muse, mutect2, varscan2
- CLIP1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56799530; called by muse, mutect2, varscan2
- CLSPN | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV52048576; called by muse, mutect2, varscan2
- CPEB1 | c.1065G>C p.W355C (on ENST00000617958; = p.W295C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55617937; called by muse, mutect2
- CPOX | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51637830; called by muse, mutect2, varscan2
- CTNNA1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV57072255; called by muse, mutect2, varscan2
- CUBN | c.7348G>A p.E2450K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100912429; called by muse, mutect2
- CUL7 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54814544; called by muse, mutect2, varscan2
- DDX24 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.117); catalogued as COSV58212082; called by muse, mutect2, varscan2
- DENND5A | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.867); catalogued as COSV60232556; called by muse, mutect2, varscan2
- DGKG | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV53962903; called by muse, mutect2, varscan2
- DGUOK | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51203309; called by mutect2, varscan2
- DIDO1 | c.5409G>C p.Q1803H | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV56617298, COSV56619349, COSV56637594; called by muse, mutect2, varscan2
- DIP2C | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV55151417; called by muse, mutect2, varscan2
- DOCK4 | c.5195A>T p.E1732V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV70234360, COSV70234888; called by muse, mutect2, varscan2
- DPH1 | c.1256C>G p.S419W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV53984061; called by muse, mutect2, varscan2
- DPP9 | c.490G>A p.D164N (on ENST00000598800; = p.D193N on NM_139159.5) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1214113309, COSV53590008, COSV53593505; called by muse, mutect2, varscan2
- DST | c.16270G>C p.E5424Q (on ENST00000361203 / NM_001374722.1; = p.E3012Q on NM_015548.5) | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.97); catalogued as COSV55005217; called by muse, mutect2, varscan2
- DYNC1H1 | c.3881G>C p.R1294T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.331); catalogued as COSV64135365; called by muse, mutect2, varscan2
- DYNC2H1 | c.11203C>T p.Q3735* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100518187; called by muse, mutect2, varscan2
- EDIL3 | c.651+1G>A p.X217_splice | Splice Site (SNP) | VAF 30/138 reads (22%) | catalogued as rs113301797, COSV56888388; called by muse, mutect2
- EFHC1 | c.858T>G p.D286E | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV64135837; called by muse, mutect2, varscan2
- EPHA3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV60699220, COSV60706097; called by muse, mutect2, varscan2
- ESPL1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs367795450, COSV57758382; called by muse, mutect2, varscan2
- ESYT1 | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57272116; called by muse, mutect2, varscan2
- ETNPPL | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); catalogued as COSV56595159; called by muse, mutect2, varscan2
- EXOSC10 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV58664578; called by muse, mutect2, varscan2
- F12 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316388419, COSV99499572; called by muse, mutect2
- FAM199X | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); catalogued as COSV55433385; called by muse, mutect2, varscan2
- FAM47B | c.606G>T p.Q202H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs17855582, COSV61453068; called by muse, mutect2, varscan2
- FAM47B | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.271); catalogued as COSV61453074; called by muse, mutect2, varscan2
- FCER1A | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV63666837; called by muse, mutect2, varscan2
- FLG2 | c.4349C>G p.A1450G | Missense Mutation (SNP) | VAF 106/600 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66167429; called by muse, mutect2, varscan2
- FLRT2 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 91/341 reads (27%) | catalogued as COSV100420243; called by muse, mutect2, varscan2
- FLRT2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 50/240 reads (21%) | catalogued as COSV100420244; called by muse, mutect2, varscan2
- FMNL2 | c.1415T>G p.I472S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV56492257; called by muse, mutect2, varscan2
- FN3KRP | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53929222, COSV53929666; called by muse, mutect2, varscan2
- GAA | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56407703; called by muse, mutect2, varscan2
- GAN | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV101633975; called by muse, mutect2, varscan2
- GAPVD1 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV52921780; called by muse, mutect2, varscan2
- GCC2 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs775266412, COSV59174129, COSV59175083; called by muse, mutect2, varscan2
- GCN1 | c.7286C>G p.S2429* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100324453, COSV100324981; called by muse, mutect2, varscan2
- GDF9 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51526031; called by muse, mutect2, varscan2
- GFM1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV51831856; called by muse, mutect2, varscan2
- GKAP1 | c.807C>G p.I269M | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64487337; called by muse, mutect2, varscan2
- GLDC | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV58678315, COSV58682679; called by muse, mutect2, varscan2
- GPBP1L1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as COSV51968085; called by muse, mutect2, varscan2
- GPR78 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV66762736; called by muse, mutect2
- GPS1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as rs371123465, COSV57647681; called by muse, mutect2, varscan2
- GRAMD1C | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63982280; called by muse, mutect2
- GRM6 | c.1217A>T p.D406V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51437579; called by muse, mutect2, varscan2
- GRN | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as rs201686997, COSV50006649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF3C3 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs758881739, COSV55831507; called by muse, mutect2, varscan2
- GUCY2F | c.423C>G p.S141R | Missense Mutation (SNP) | VAF 178/335 reads (53%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.449); catalogued as COSV54300060; called by muse, mutect2, varscan2
- HCN4 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV56082330; called by muse, mutect2, varscan2
- HGS | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.545); catalogued as COSV61267133; called by muse, mutect2, varscan2
- HHIPL1 | c.612T>A p.D204E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58089754; called by muse, mutect2, varscan2
- HLA-E | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.931); catalogued as rs376826280, COSV64927395; called by muse, mutect2, varscan2
- HNRNPH1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV61485206; called by muse, mutect2, varscan2
- HTR3D | c.1207G>A p.E403K (on ENST00000382489 / NM_001163646.2; = p.E228K on NM_182537.3) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV100488032; called by muse, mutect2, varscan2
- HTRA3 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56470359; called by muse, mutect2, varscan2
- HUWE1 | c.2698C>T p.H900Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV53339653, COSV99470530; called by muse, mutect2, varscan2
- IER5 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100849679; called by muse, mutect2, varscan2
- IGF2BP1 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51730173, COSV51736274, COSV99288339; called by muse, mutect2, varscan2
- IGFBP4 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV54096989; called by muse, mutect2, varscan2
- IGSF10 | c.3938C>G p.S1313* | Nonsense Mutation (SNP) | VAF 34/425 reads (8%) | catalogued as COSV99178323; called by muse, mutect2
- IKBIP | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV61081449; called by muse, mutect2, varscan2
- IL1RN | c.487G>C p.D163H (on ENST00000409930 / NM_173842.3; = p.D145H on NM_000577.5) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV52080208; called by muse, mutect2, varscan2
- IMMT | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99607163; called by muse, mutect2, varscan2
- INHBE | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.825); catalogued as COSV56987739; called by muse, mutect2, varscan2
- IQSEC1 | c.2512G>C p.V838L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56222574; called by muse, mutect2, varscan2
- IRF5 | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50857089; called by muse, mutect2, varscan2
- ITIH2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs923997175, COSV64432565; called by muse, mutect2, varscan2
- ITSN2 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV61945109; called by muse, mutect2, varscan2
- JMJD7 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59823091; called by muse, mutect2, varscan2
- KCND2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.309); catalogued as COSV58574057; called by muse, mutect2, varscan2
- KCNE1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs199473350, CM056968, COSV61606438; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.045); catalogued as COSV100059703; called by muse, mutect2
- KCNH7 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59791387; called by muse, mutect2, varscan2
- KCNK16 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV64677612; called by muse, mutect2, varscan2
- KDM7A | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50090570; called by muse, mutect2, varscan2
- KIAA0895 | c.433C>T p.R145C (on ENST00000297063 / NM_001100425.2; = p.R94C on NM_015314.3) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.431); catalogued as rs201511349, COSV51709631; called by muse, mutect2, varscan2
- KIAA2026 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1427482456, COSV67354135; called by muse, mutect2, varscan2
- KIAA2026 | c.600G>C p.L200F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751585899, COSV101198959, COSV67353249; called by muse, mutect2
- KLHL11 | c.761C>G p.S254* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100044278, COSV59861442; called by muse, mutect2, varscan2
- KLHL15 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV100044214, COSV60139647; called by muse, mutect2, varscan2
- KMT2A | c.6755C>G p.S2252* | Nonsense Mutation (SNP) | VAF 19/140 reads (14%) | catalogued as COSV100628524; called by muse, mutect2, varscan2
- KMT2D | c.2317del p.Q773Sfs*157 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as COSV56443963; called by mutect2, pindel, varscan2
- LAMA2 | c.3113G>C p.G1038A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70343324; called by muse, mutect2, varscan2
- LATS1 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.074); catalogued as rs1482018073, COSV53588312; called by muse, mutect2, varscan2
- LATS1 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV53588346, COSV99486280; called by muse, mutect2, varscan2
- LONRF2 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66540116; called by muse, mutect2, varscan2
- LPA | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.549); catalogued as rs957300092, COSV100306582; called by muse, mutect2, varscan2
- LRP1B | c.11850G>C p.R3950S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV67200432; called by muse, mutect2, varscan2
- LRRC37A3 | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 46/597 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.423); catalogued as COSV100140973, COSV59760619; called by muse, mutect2
- LRRC59 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56814097; called by muse, mutect2, varscan2
- MAGEC1 | c.1679C>G p.S560C | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV53570176, COSV99597043; called by muse, mutect2, varscan2
- MANBAL | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65311493; called by muse, mutect2, varscan2
- MAP3K14 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.255); catalogued as COSV60923082; called by muse, mutect2, varscan2
- MAPK10 | c.731C>T p.P244L (on ENST00000359221 / NM_001351625.2; = p.P282L on NM_002753.5) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60378794; called by muse, mutect2
- MAPKBP1 | c.4024G>A p.E1342K (on ENST00000456763 / NM_001128608.2; = p.E1336K on NM_014994.3) | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as rs140684640, COSV52959496, COSV52961349; called by muse, mutect2, varscan2
- MARK4 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99488172; called by muse, mutect2, varscan2
- MAST4 | c.826G>T p.A276S (on ENST00000403625 / NM_001164664.2; = p.A87S on NM_015183.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55119869; called by muse, mutect2, varscan2
- MBIP | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV59253615; called by muse, mutect2, varscan2
- MBTD1 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as COSV64503086, COSV64503154; called by muse, mutect2, varscan2
- MCF2 | c.2585T>A p.V862E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.045); catalogued as COSV58480981; called by muse, mutect2, varscan2
- MCM6 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.41); catalogued as rs779470520, COSV51465370; called by muse, mutect2, varscan2
- MED13 | c.3554C>G p.S1185C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV67262704; called by muse, mutect2, varscan2
- MEP1A | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); catalogued as rs764569906, COSV57919023; called by muse, mutect2, varscan2
- MFN1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54938833; called by muse, mutect2, varscan2
- MGAT5B | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1473214762, COSV100047750; called by muse, mutect2
- MKRN3 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV58809286; called by muse, mutect2, varscan2
- MPDZ | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59937783; called by muse, mutect2
- MSANTD1 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.671); catalogued as COSV70873204; called by muse, mutect2, varscan2
- MYF5 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV57354345, COSV57354486, COSV57354743; called by muse, mutect2, varscan2
- MYOM1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as rs1324366209, COSV55288068; called by muse, mutect2
- MYOM2 | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as rs765885771, COSV50705916; called by muse, mutect2, varscan2
- N4BP1 | c.2366A>G p.N789S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1175239155, COSV52210218; called by muse, mutect2, varscan2
- NCR2 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66100326; called by muse, mutect2, varscan2
- NEK10 | c.2750C>A p.S917* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV99835029; called by muse, mutect2, varscan2
- NID2 | c.2447C>G p.S816C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53494444; called by muse, mutect2, varscan2
- NKAPD1 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54775114; called by muse, mutect2, varscan2
- NKD1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs758306906, COSV51690333; called by muse, mutect2, varscan2
- NKPD1 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521548; called by muse, mutect2, varscan2
- NUP98 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV61430336; called by muse, mutect2, varscan2
- OPA3 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54398543; called by muse, mutect2, varscan2
- OR14J1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV65845587; called by muse, mutect2, varscan2
- OR2A14 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68718053; called by muse, mutect2, varscan2
- OR4B1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV58882318; called by muse, mutect2, varscan2
- OR5D13 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV62333205; called by muse, mutect2, varscan2
- OR5V1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as COSV101011207; called by muse, mutect2, varscan2
- OR8B3 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.065); catalogued as COSV100660394, COSV63542022; called by muse, mutect2
- PAK2 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV59080189; called by muse, mutect2, varscan2
- PAPPA2 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 79/271 reads (29%) | catalogued as COSV100866715; called by muse, mutect2, varscan2
- PARD3 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60747139; called by muse, mutect2, varscan2
- PARP8 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55858227; called by muse, mutect2, varscan2
- PARP9 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1423311055, COSV100830918, COSV64450320, COSV64450697; called by muse, mutect2, varscan2
- PCDHA2 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100973779; called by muse, mutect2, varscan2
- PCDHGB3 | c.2374G>T p.D792Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV99535475; called by muse, mutect2
- PCNP | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54575609; called by muse, mutect2, varscan2
- PDE12 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as COSV60818332; called by muse, varscan2
- PDE3B | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs762967876, COSV56381474; called by muse, mutect2, varscan2
- PEPD | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV54888468; called by muse, mutect2, varscan2
- PGBD1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV52552142; called by muse, mutect2, varscan2
- PHF8 | c.2600G>A p.R867Q (on ENST00000357988 / NM_001184896.1; = p.R831Q on NM_015107.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV57679127; called by muse, mutect2, varscan2
- PPIG | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53642090; called by muse, mutect2, varscan2
- PPM1G | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV59768901; called by muse, mutect2, varscan2
- PRDM14 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV99400044; called by muse, mutect2, varscan2
- PRDM2 | c.1676C>G p.S559C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52444518; called by muse, mutect2
- PRDM2 | c.3089C>G p.S1030C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52444529; called by muse, mutect2, varscan2
- PRRC2A | c.4125G>C p.Q1375H | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV65685825; called by muse, mutect2, varscan2
- PRRC2A | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV65685830; called by muse, mutect2, varscan2
- PRSS12 | c.2128C>A p.Q710K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV56605190; called by muse, mutect2, varscan2
- QRSL1 | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100945413; called by muse, mutect2
- RABGEF1 | c.733G>A p.E245K (on ENST00000439720 / NM_001287061.2; = p.E232K on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53161445; called by muse, mutect2, varscan2
- RALGAPA1 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354197; called by muse, mutect2, varscan2
- RALY | c.889G>C p.D297H (on ENST00000246194 / NM_016732.3; = p.D281H on NM_007367.4) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55780496; called by muse, mutect2, varscan2
- RANBP2 | c.8224G>C p.D2742H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51698656, COSV51700777, COSV99311820; called by muse, mutect2
- RASSF6 | c.880G>A p.E294K (on ENST00000342081 / NM_201431.2; = p.E262K on NM_177532.5) | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56717177; called by muse, mutect2, varscan2
- RASSF9 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV63432963, COSV63433208; called by muse, mutect2, varscan2
- RB1 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as CM1312466, COSV57321229; called by muse, mutect2, varscan2
- RBL1 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100726972; called by muse, mutect2, varscan2
- RCC1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65779172; called by muse, varscan2
- RDH16 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100660089; called by muse, mutect2, varscan2
- RING1 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100761750; called by muse, mutect2, varscan2
- RNF125 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV54184008; called by muse, mutect2, varscan2
- RNF144A | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57981476; called by muse, mutect2, varscan2
- RNF17 | c.4403A>C p.N1468T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759297455, COSV55036839; called by muse, mutect2, varscan2
- ROBO2 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1356551506, COSV100165806; called by muse, mutect2
- RYR2 | c.14746G>A p.A4916T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63674552, COSV63707562; called by muse, mutect2, varscan2
- SALL4 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs370485562, COSV53851012; called by muse, mutect2, varscan2
- SCN3A | c.4120G>C p.D1374H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV51805516, COSV99328857; called by muse, mutect2, varscan2
- SEC14L4 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55399048; called by muse, mutect2, varscan2
- SELE | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.175); catalogued as COSV60974587; called by muse, mutect2
- SEMA3E | c.2097G>C p.Q699H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57083947; called by muse, mutect2, varscan2
- SEMA6A | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56710106; called by muse, mutect2, varscan2
- SHC1 | c.1701C>G p.I567M (on ENST00000368445 / NM_183001.5; = p.I458M on NM_003029.5) | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV63534653; called by muse, mutect2
- SHC2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs375705853; called by muse, mutect2, varscan2
- SKIDA1 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV71610435, COSV71610779; called by muse, mutect2, varscan2
- SLA2 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53410711; called by muse, mutect2, varscan2
- SLC12A7 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs375450378; called by muse, mutect2, varscan2
- SLC29A2 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); catalogued as COSV100237059, COSV60803049; called by muse, mutect2, varscan2
- SLCO6A1 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV65807924; called by muse, mutect2, varscan2
- SMAD2 | c.1351A>G p.K451E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV50994504; called by muse, mutect2, varscan2
- SMC5 | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV63192246; called by muse, mutect2, varscan2
- SMPD4 | c.1156G>C p.E386Q (on ENST00000409031 / NM_017951.4; = p.E357Q on NM_017751.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as COSV100302399; called by muse, mutect2, varscan2
- SNRPB | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100293279, COSV60016586; called by muse, mutect2, varscan2
- SNTG1 | c.45T>A p.C15* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99382941; called by muse, mutect2, varscan2
- SNX14 | c.1234G>C p.D412H (on ENST00000314673 / NM_001350535.1; = p.D368H on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59009447; called by muse, mutect2
- SORCS1 | c.2825C>A p.S942Y | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV53852447, COSV99547756; called by muse, mutect2, varscan2
- SORL1 | c.3288G>C p.W1096C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.518); catalogued as rs1477603016, COSV52750509; called by muse, mutect2, varscan2
- SP100 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as COSV50975917; called by muse, mutect2, varscan2
- SPATA12 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.924); catalogued as COSV57589292, COSV57589420; called by muse, mutect2, varscan2
- SPATA5 | c.2376C>G p.I792M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV56773785; called by muse, mutect2, varscan2
- SPATS1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV55822419; called by muse, mutect2, varscan2
- SPDL1 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778730988, COSV54667024; called by muse, mutect2, varscan2
- SRPK1 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs202045785; called by muse, mutect2, varscan2
- SSPN | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs867658451, COSV54380732; called by muse, mutect2, varscan2
- SYNE1 | c.19338G>C p.E6446D (on ENST00000367255 / NM_182961.4; = p.E6375D on NM_033071.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV54902872, COSV54940888; called by muse, mutect2, varscan2
- SYNE2 | c.17557-1G>A p.X5853_splice | Splice Site (SNP) | VAF 96/439 reads (22%) | catalogued as COSV59944646; called by muse, mutect2, varscan2
- SZT2 | c.6118G>T p.V2040F (on ENST00000634258 / NM_001365999.1; = p.V1983F on NM_015284.4) | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100987547, COSV65168447; called by muse, mutect2, varscan2
- TAF2 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100978885, COSV65417379; called by muse, mutect2, varscan2
- TERF1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as COSV52577282; called by muse, varscan2
- TFEB | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824203; called by muse, mutect2, varscan2
- TMEM179B | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV53667697; called by muse, mutect2, varscan2
- TNFRSF21 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV57280967; called by muse, mutect2, varscan2
- TPM4 | c.234G>A p.M78I (on ENST00000300933; = p.E86K on NM_003290.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV56288441; called by muse, mutect2, varscan2
- TRIM27 | c.920-1G>A p.X307_splice | Splice Site (SNP) | VAF 19/62 reads (31%) | catalogued as COSV65873387; called by muse, mutect2, varscan2
- TRIM33 | c.1159G>C p.V387L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.082); catalogued as COSV61821606; called by muse, mutect2
- TRIO | c.9063G>C p.Q3021H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV59989466; called by muse, mutect2, varscan2
- TRMT2A | c.1550-1G>T p.X517_splice | Splice Site (SNP) | VAF 28/95 reads (29%) | catalogued as COSV52812850; called by muse, mutect2, varscan2
- TTC21B | c.3713G>C p.G1238A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54628976; called by muse, mutect2, varscan2
- TTC25 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782333806, COSV101102925; called by muse, mutect2, varscan2
- TTC37 | c.2641C>A p.H881N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV62454188; called by muse, mutect2, varscan2
- TTN | c.36335C>T p.A12112V (on ENST00000591111; = p.A4688V on NM_003319.4) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | PolyPhen benign (0.356); catalogued as COSV59958949; called by muse, mutect2, varscan2
- UBE3D | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs767563891, COSV52708331; called by muse, mutect2, varscan2
- UCKL1 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs781356780, COSV62402594; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4348G>C p.E1450Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV54435757; called by muse, mutect2
- USP47 | c.2815C>A p.Q939K (on ENST00000399455 / NM_001372095.1; = p.Q851K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV60462251; called by muse, varscan2
- UTP20 | c.6288G>C p.K2096N | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55374479; called by muse, mutect2, varscan2
- VPS33A | c.1368G>C p.Q456H | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV57356503; called by muse, mutect2, varscan2
- VPS39 | c.493G>C p.D165H (on ENST00000348544 / NM_001301138.2; = p.D154H on NM_015289.5) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58788645; called by muse, mutect2, varscan2
- VWF | c.7805C>T p.T2602I | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV54615414; called by muse, mutect2, varscan2
- WDR31 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as COSV59145699; called by muse, mutect2, varscan2
- WTAP | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100603299; called by muse, mutect2
- XIRP1 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61137599; called by muse, mutect2, varscan2
- XPNPEP1 | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59167245; called by muse, mutect2, varscan2
- XRCC1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53448190; called by muse, mutect2, varscan2
- ZBTB7A | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59326722; called by muse, mutect2, varscan2
- ZDHHC5 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as COSV54705144, COSV54705852; called by muse, mutect2, varscan2
- ZHX3 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58382020, COSV58382170; called by muse, mutect2, varscan2
- ZNF182 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as COSV100527260, COSV59356502; called by muse, mutect2, varscan2
- ZNF185 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59274986; called by muse, mutect2, varscan2
- ZNF425 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65200917; called by muse, mutect2, varscan2
- ZNF425 | c.990C>G p.F330L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV65200923; called by muse, mutect2, varscan2
- ZNF507 | c.2524C>G p.Q842E | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100321668, COSV61330524; called by muse, mutect2, varscan2
- ZNF536 | c.2713C>T p.Q905* | Nonsense Mutation (SNP) | VAF 80/390 reads (21%) | catalogued as COSV100835031; called by muse, mutect2, varscan2
- ZNF547 | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56579405; called by muse, mutect2, varscan2
- ZNF568 | c.1682A>G p.N561S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as COSV61740903; called by muse, mutect2, varscan2
- ZNF675 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.375); catalogued as COSV63095516; called by muse, mutect2, varscan2
- ZSWIM3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV54846099; called by muse, mutect2, varscan2
- CADM3 | c.125_139del p.A42_V46del (on ENST00000368125 / NM_001127173.3; = p.A76_V80del on NM_021189.5) | In Frame Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- MRC1 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.03); called by muse, mutect2
- AC011462.1 | c.882C>T p.I294= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as COSV54196371; called by muse, mutect2, varscan2
- AC092143.1 | c.1665C>T p.Y555= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as rs1159729194, COSV59247420; called by muse, mutect2, varscan2
- ACACA | c.3672T>A p.S1224= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- ACTN3 | c.2328G>A p.Q776= | Silent (SNP) | VAF 44/243 reads (18%) | catalogued as COSV59748046; called by muse, mutect2, varscan2
- AK7 | c.2040G>A p.L680= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV50870117; called by muse, mutect2, varscan2
- AP1M2 | c.571C>T p.L191= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV51566172; called by muse, mutect2, varscan2
- ASXL3 | c.3720T>G p.V1240= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV52461693; called by muse, mutect2, varscan2
- ATP10A | c.3708C>T p.F1236= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV63515345; called by muse, mutect2, varscan2
- ATP11A | c.1401C>T p.R467= | Silent (SNP) | VAF 101/458 reads (22%) | catalogued as rs902132465, COSV52108652; called by muse, mutect2, varscan2
- AVIL | c.2410C>T p.L804= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV57680944; called by muse, mutect2, varscan2
- BRAP | c.1645C>T p.L549= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV59535940; called by muse, mutect2, varscan2
- BRINP1 | c.2208C>T p.I736= | Silent (SNP) | VAF 59/232 reads (25%) | catalogued as COSV56295978; called by muse, mutect2, varscan2
- C17orf50 | c.417C>G p.L139= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CALD1 | c.354G>A p.Q118= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV62646374; called by muse, mutect2, varscan2
- CBLIF | c.237C>G p.L79= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV57238374; called by muse, mutect2, varscan2
- CCNB1 | c.534G>A p.L178= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV56509580; called by muse, mutect2, varscan2
- CDHR5 | c.900C>T p.F300= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV57642077; called by muse, mutect2, varscan2
- CEP95 | c.69G>T p.L23= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV56748524; called by muse, mutect2, varscan2
- CFAP65 | c.3870G>A p.V1290= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV58559249; called by mutect2, varscan2
- CGREF1 | c.399C>T p.L133= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs758399410, COSV53149082; called by muse, mutect2, varscan2
- CHRNA2 | c.714C>G p.G238= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV53556983; called by muse, mutect2, varscan2
- CIT | c.4533C>T p.S1511= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs142811369, COSV55861655, COSV55864148; called by muse, mutect2, varscan2
- CLASP1 | c.81G>T p.L27= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV55318632; called by muse, mutect2, varscan2
- CLCA1 | c.1044A>G p.T348= | Silent (SNP) | VAF 60/188 reads (32%) | catalogued as COSV52326797; called by muse, mutect2, varscan2
- CLDN4 | c.33C>T p.I11= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs146691861, COSV52895648; called by muse, mutect2, varscan2
- COPB2 | c.1794C>T p.V598= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV60812167; called by muse, mutect2, varscan2
- CORO2A | c.1047C>T p.L349= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV59662618; called by muse, mutect2, varscan2
- CPA3 | c.1137C>T p.L379= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV56043435, COSV56044399; called by muse, mutect2, varscan2
- CUL4A | c.963G>A p.Q321= (on ENST00000375440 / NM_001008895.4; = p.Q221= on NM_003589.3) | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as COSV58371896; called by muse, mutect2, varscan2
- CYP7A1 | c.234C>T p.F78= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs1421941457, COSV56962993; called by muse, mutect2, varscan2
- DCBLD2 | c.891G>A p.G297= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV58788432; called by muse, mutect2, varscan2
- DLGAP5 | c.1797G>T p.V599= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV55962636, COSV99903675; called by muse, mutect2, varscan2
- DNAH8 | c.12420G>A p.K4140= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV59434549; called by muse, mutect2, varscan2
- DNTTIP1 | c.294G>C p.L98= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54784179, COSV54784704; called by muse, mutect2
- DSCAML1 | c.2712C>T p.N904= (on ENST00000321322; = p.N844= on NM_020693.4) | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs767055301, COSV58386164; called by muse, mutect2, varscan2
- DST | c.3267G>A p.Q1089= (on ENST00000361203 / NM_001374722.1; = p.Q763= on NM_001723.6) | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV55005234; called by muse, mutect2, varscan2
- ENG | c.1344C>G p.L448= | Silent (SNP) | VAF 85/408 reads (21%) | catalogued as COSV61226797; called by muse, varscan2
- ENPP2 | c.9G>A p.R3= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs761158154, COSV50011748; called by muse, mutect2, varscan2
- ETNK2 | c.954G>A p.G318= | Silent (SNP) | VAF 61/260 reads (23%) | catalogued as rs775624367, COSV65819701; called by muse, mutect2, varscan2
- FBXL2 | c.369T>C p.Y123= | Silent (SNP) | VAF 103/387 reads (27%) | catalogued as rs753620211, COSV52137633; called by muse, mutect2, varscan2
- FSCN1 | c.612G>A p.A204= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100435115; called by muse, mutect2
- GRIN2A | c.1945C>T p.L649= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as CM1211494, COSV58020392, COSV58055559, COSV58057887; called by muse, mutect2, varscan2
- GRIP1 | c.39G>A p.L13= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV54019186; called by muse, mutect2, varscan2
- H1-3 | c.135C>T p.I45= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as rs200463287, COSV55097131, COSV99768859; called by muse, mutect2, varscan2
- HAGHL | c.27C>G p.L9= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52401457; called by muse, mutect2, varscan2
- HMCN1 | c.2964G>A p.Q988= | Silent (SNP) | VAF 32/213 reads (15%) | catalogued as COSV54887761; called by muse, mutect2, varscan2
- HTR5A | c.432G>A p.T144= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV55281723; called by muse, mutect2, varscan2
- IGHV3-72 | c.144C>T p.F48= | Silent (SNP) | VAF 46/249 reads (18%) | catalogued as rs771755878, COSV70409558; called by muse, mutect2, varscan2
- ISL2 | c.756C>T p.L252= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs145440339; called by muse, mutect2
- ITGB5 | c.75C>G p.L25= | Silent (SNP) | VAF 45/490 reads (9%) | catalogued as COSV56147791; called by muse, mutect2
- KCNK4 | c.996C>G p.P332= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs1344470147, COSV60453743; called by muse, mutect2, varscan2
- KMT2C | c.2457C>T p.V819= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs777011633, COSV51422366; called by muse, mutect2
- LCT | c.291C>T p.L97= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs751958334, COSV51465360; called by muse, mutect2, varscan2
- LINGO1 | c.732G>A p.L244= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs1216933473, COSV62436514; called by muse, mutect2
- MRPL37 | c.474C>T p.I158= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100288967, COSV60321353; called by muse, mutect2, varscan2
- MYO7A | c.513C>A p.I171= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as rs375366269; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK5 | c.1314G>A p.Q438= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV62879358; called by muse, mutect2, varscan2
- OR2T10 | c.426C>G p.L142= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as COSV57896191, COSV57896291, COSV57896464; called by muse, mutect2, varscan2
- OR5K3 | c.762C>G p.L254= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV67349765, COSV67349828; called by muse, mutect2, varscan2
- OR8B4 | c.570C>T p.S190= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs756679737, COSV62069492; called by muse, mutect2, varscan2
- OTUD7B | c.2514C>A p.L838= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as COSV64915654; called by muse, mutect2, varscan2
- PAQR5 | c.712C>T p.L238= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV61817667; called by muse, mutect2, varscan2
- PCDH17 | c.3408G>A p.E1136= | Silent (SNP) | VAF 89/420 reads (21%) | catalogued as COSV64972957; called by muse, mutect2, varscan2
- PCDHGC5 | c.18C>G p.L6= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV52747142; called by muse, mutect2, varscan2
- PDE7A | c.63C>T p.L21= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV67523482; called by muse, mutect2, varscan2
- PLEK2 | c.222G>T p.L74= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as COSV53604544; called by muse, mutect2, varscan2
- PPFIBP2 | c.2157C>T p.S719= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV55075601; called by muse, mutect2, varscan2
- PSMD6 | c.210C>G p.L70= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV55759258; called by muse, varscan2
- PTGER2 | c.567C>T p.I189= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs780303158, COSV55418519; called by muse, mutect2, varscan2
- RPL36 | c.117C>T p.F39= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as rs1264148786, COSV56798032; called by muse, mutect2, varscan2
- RRAS | c.531C>G p.L177= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV55868343; called by muse, mutect2, varscan2
- RRP8 | c.807C>G p.L269= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54449164; called by muse, mutect2, varscan2
- RTN4RL2 | c.780T>A p.A260= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV58651512; called by muse, mutect2, varscan2
- SELP | c.2034C>T p.L678= | Silent (SNP) | VAF 324/777 reads (42%) | catalogued as rs1425842605, COSV55249966; called by muse, mutect2, varscan2
- SEMA4B | c.1314G>C p.L438= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV60172973; called by muse, mutect2, varscan2
- SF3B2 | c.1803G>A p.L601= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs772089425, COSV59427502; called by muse, mutect2, varscan2
- SGK1 | c.174G>A p.L58= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV52805684, COSV52808137; called by muse, mutect2, varscan2
- SIPA1L2 | c.1629G>A p.L543= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV53398573; called by muse, mutect2
- SIX1 | c.228G>A p.S76= | Silent (SNP) | VAF 90/411 reads (22%) | catalogued as rs753360604, COSV55959548; called by muse, mutect2, varscan2
- SPATA31D1 | c.1068C>T p.F356= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV61194116; called by muse, mutect2, varscan2
- SRD5A2 | c.156C>A p.A52= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV51871005; called by muse, mutect2, varscan2
- SSUH2 | c.705G>A p.K235= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV58029527; called by muse, mutect2, varscan2
- THNSL2 | c.900C>T p.F300= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV59082372; called by muse, mutect2, varscan2
- THRSP | c.168C>T p.L56= | Silent (SNP) | VAF 48/221 reads (22%) | catalogued as COSV55246105; called by muse, mutect2, varscan2
- TMC3 | c.1557C>T p.T519= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs778542455, COSV63922616; called by muse, mutect2, varscan2
- TMEM223 | c.505C>T p.L169= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53667700; called by muse, mutect2, varscan2
- TMPRSS4 | c.138C>T p.I46= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV71108643; called by muse, mutect2, varscan2
- TNC | c.4662T>C p.N1554= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV60782929; called by muse, mutect2, varscan2
- TNFRSF10B | c.282C>T p.C94= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs751882895, COSV52391509; called by muse, mutect2, varscan2
- TOMM5 | c.21C>G p.L7= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs202059576, COSV100353574, COSV58375455; called by muse, mutect2, varscan2
- TRPM6 | c.2856G>A p.R952= | Silent (SNP) | VAF 64/329 reads (19%) | catalogued as COSV62505866; called by muse, mutect2, varscan2
- TSN | c.21C>T p.F7= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs750437337, COSV67605207; called by muse, mutect2, varscan2
- TUBB2B | c.762G>T p.A254= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs573534407; called by muse, varscan2
- TUBGCP3 | c.1263C>T p.L421= | Silent (SNP) | VAF 55/270 reads (20%) | catalogued as rs147627552; called by muse, mutect2, varscan2
- UGT2A3 | c.919C>T p.L307= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as COSV52359447; called by muse, mutect2, varscan2
- USP47 | c.2736C>G p.L912= (on ENST00000399455 / NM_001372095.1; = p.L824= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV60462230; called by muse, varscan2
- WNT8A | c.675G>A p.L225= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV64230969; called by muse, mutect2, varscan2
- ZDHHC11 | c.1128C>T p.D376= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as rs747162519, COSV52065060, COSV52069707; called by muse, mutect2, varscan2
- ZDHHC5 | c.432G>C p.R144= | Silent (SNP) | VAF 58/217 reads (27%) | catalogued as COSV54705840; called by muse, mutect2, varscan2
- ZFX | c.1170C>T p.L390= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV58446892; called by muse, mutect2, varscan2
- ZNF273 | c.84C>T p.L28= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as rs372606222; called by muse, mutect2, varscan2
- ZNF33A | c.531C>T p.L177= (on ENST00000458705 / NM_006974.3; = p.L178= on NM_006954.2) | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV56723991; called by muse, mutect2, varscan2
- ZNF425 | c.783C>T p.L261= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs1454020101, COSV65200927; called by muse, mutect2, varscan2
- ZNF425 | c.582C>A p.V194= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs774729328, COSV65200932; called by muse, mutect2, varscan2
- ZNF425 | c.321C>T p.P107= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV65200938; called by muse, mutect2, varscan2
- ZNF514 | c.30C>T p.F10= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs766042381, COSV54633555; called by muse, mutect2, varscan2
- CD300LD | chr17:74592327 C>T | 5'Flank (SNP) | VAF 21/103 reads (20%) | catalogued as rs1398551730; called by muse, mutect2, varscan2
- EXOC3 | chr5:442535 G>C | 5'Flank (SNP) | VAF 42/211 reads (20%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-35271A>T | Intron (SNP) | VAF 47/242 reads (19%) | catalogued as COSV99399192; called by muse, mutect2, varscan2
- MAGEA5 | n.291C>T | RNA (SNP) | VAF 94/215 reads (44%) | called by muse, mutect2, varscan2
- MFSD4B | c.*804G>C | 3'UTR (SNP) | VAF 30/156 reads (19%) | catalogued as COSV64348692; called by muse, mutect2, varscan2
- PDGFD | c.125-36729G>A | Intron (SNP) | VAF 65/271 reads (24%) | catalogued as rs750524810, COSV56372381; called by muse, mutect2, varscan2
- PSMB1 | c.*1T>C | 3'UTR (SNP) | VAF 41/203 reads (20%) | catalogued as COSV100079839; called by muse, mutect2, varscan2
- RPL4 | c.676+64G>A | Intron (SNP) | VAF 15/114 reads (13%) | catalogued as COSV100328562; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51579C>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV67442059; called by muse, mutect2, varscan2
- STARD7-AS1 | n.1454C>T | RNA (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3021G>C | Intron (SNP) | VAF 31/155 reads (20%) | catalogued as COSV100954053, COSV65184983; called by muse, mutect2, varscan2
